Somatic mutation profile of tumor specimen TCGA-BW-A5NP-01A (aliquot TCGA-BW-A5NP-01A-11D-A27I-10) from TCGA case TCGA-BW-A5NP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 26.9 years (9,809 days).
Specimen TCGA-BW-A5NP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47cc09a3-2697-4c4c-83c2-9bb28c9fb893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BW-A5NP-10A (Blood Derived Normal), aliquot TCGA-BW-A5NP-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca2ff0f9-f1a3-4464-87eb-6e62887523a1

The open-access MAF lists 78 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Nonsense Mutation 3, 3'UTR 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA12 | c.3191G>T p.S1064I (on ENST00000272895 / NM_173076.3; = p.S746I on NM_015657.3) | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV55959431; called by muse, mutect2, varscan2
- ABCA13 | c.14332G>A p.A4778T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV68946810; called by muse, mutect2, varscan2
- ADCY5 | c.2437G>A p.V813I | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs372853437, COSV59196147; called by muse, mutect2, varscan2
- AGBL2 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 47/92 reads (51%) | catalogued as COSV54092046; called by muse, mutect2, varscan2
- AQP5 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs901182462, COSV53311190; called by muse, mutect2, varscan2
- ASAP1 | c.803T>G p.L268R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63048617; called by muse, mutect2, varscan2
- ATRNL1 | c.2606G>A p.G869D | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58088612; called by muse, mutect2, varscan2
- BCORL1 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV54396320; called by muse, mutect2, varscan2
- BCORL1 | c.4232A>T p.E1411V | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54396340; called by muse, mutect2, varscan2
- C5orf52 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV69625993; called by muse, mutect2
- CCT3 | c.845T>A p.I282N | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55289026; called by muse, mutect2, varscan2
- CDC42BPA | c.4864C>T p.P1622S (on ENST00000334218 / NM_001366019.2; = p.P1609S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100503349; called by muse, mutect2
- CHST2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58885568; called by muse, mutect2, varscan2
- CNTNAP4 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 65/71 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56680541; called by muse, mutect2, varscan2
- CRB1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV66341002, COSV66347423; called by muse, mutect2
- DHX16 | c.416A>C p.E139A | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64580609; called by muse, mutect2
- DTNA | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs374916548; called by muse, mutect2, varscan2
- DUOX2 | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66531447, COSV66532801; called by muse, mutect2, varscan2
- EDNRB | c.860T>A p.I287N (on ENST00000377211 / NM_001201397.1; = p.I197N on NM_000115.5) | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57522622; called by muse, varscan2
- EPHA3 | c.1664T>A p.L555H | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV60705840; called by muse, mutect2, varscan2
- FLI1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as COSV55644520; called by muse, mutect2, varscan2
- FLT1 | c.1796C>G p.T599R | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV56727865; called by muse, mutect2
- GRK6 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV62682614; called by muse, varscan2
- HPGD | c.262T>A p.L88M | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.456); catalogued as COSV56662778; called by muse, mutect2
- IGF1R | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs201778894, COSV51287770; called by muse, mutect2, varscan2
- ITGB4 | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52325903; called by muse, mutect2, varscan2
- ITSN2 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as COSV61947324; called by muse, mutect2, varscan2
- KIAA1109 | c.8221C>G p.P2741A | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52673036; called by muse, mutect2, varscan2
- KIF13A | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.951); catalogued as rs184686655, COSV99436244; called by muse, varscan2
- LCLAT1 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs775496768, COSV100474720, COSV58373053; called by muse, mutect2, varscan2
- LRP12 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV52628857; called by muse, varscan2
- MDC1 | c.4386C>A p.D1462E | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV104426983, COSV64524614; called by muse, mutect2, varscan2
- MMRN1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV53333389; called by muse, mutect2, varscan2
- MMRN1 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV53336156; called by muse, mutect2, varscan2
- MYO15A | c.7830T>A p.H2610Q | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52756719; called by muse, mutect2
- NAALADL2 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV70295770; called by muse, mutect2, varscan2
- NUP210L | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 21/294 reads (7%) | catalogued as COSV55136193; called by muse, mutect2
- PAPPA2 | c.4784G>A p.C1595Y | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62797685; called by muse, mutect2, varscan2
- PGR | c.1685T>G p.L562* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV54801496; called by muse, mutect2, varscan2
- RNF2 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV62279353; called by muse, varscan2
- SCAPER | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs954630744, COSV57740647; called by muse, varscan2
- SLC33A1 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); catalogued as COSV63947141; called by muse, mutect2, varscan2
- SOST | c.96T>A p.D32E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1249296225, COSV57012285; called by muse, mutect2, varscan2
- SPTBN1 | c.94A>T p.N32Y | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.971); catalogued as COSV63339101; called by muse, mutect2, varscan2
- ST6GAL2 | c.865C>A p.H289N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | PolyPhen benign (0.012); catalogued as COSV64528306; called by muse, mutect2, varscan2
- TEX10 | c.1267G>C p.V423L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66515477; called by muse, mutect2, varscan2
- TMEM184A | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs967655708, COSV52473497; called by muse, mutect2, varscan2
- TTN | c.64465C>A p.P21489T (on ENST00000591111; = p.P14065T on NM_003319.4) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | PolyPhen possibly damaging (0.676); catalogued as COSV60062558; called by muse, mutect2, varscan2
- TTN | c.40834T>C p.Y13612H (on ENST00000591111; = p.Y6188H on NM_003319.4) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | PolyPhen probably damaging (0.93); catalogued as COSV60062597; called by muse, mutect2, varscan2
- USF3 | c.5201G>T p.C1734F | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57072694; called by muse, mutect2, varscan2
- WDR33 | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as COSV59247489, COSV59248987; called by muse, mutect2, varscan2
- ZBED2 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.304); catalogued as COSV51916338, COSV99343743; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV58349494; called by muse, mutect2, varscan2
- CCHCR1 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- COL2A1 | c.695_703dup p.E232_G234dup | In Frame Ins (INS) | VAF 50/195 reads (26%) | called by mutect2, varscan2
- DENND11 | c.675_676dup p.M226Rfs*2 | Frame Shift Ins (INS) | VAF 53/127 reads (42%) | called by mutect2, pindel, varscan2
- MALRD1 | c.4858C>A p.L1620I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR2AJ1 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASB13 | c.696C>T p.F232= | Silent (SNP) | VAF 55/85 reads (65%) | catalogued as rs144206251, COSV63090248; called by muse, mutect2, varscan2
- CCDC39 | c.1584C>T p.S528= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56484184; called by muse, mutect2, varscan2
- DPPA2 | c.618C>A p.S206= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV72118080; called by muse, mutect2
- DSCAM | c.4944G>T p.T1648= | Silent (SNP) | VAF 76/141 reads (54%) | catalogued as COSV68026788; called by muse, mutect2, varscan2
- DSP | c.4425C>T p.T1475= | Silent (SNP) | VAF 80/217 reads (37%) | catalogued as COSV65792775; called by muse, mutect2, varscan2
- FEN1 | c.486C>T p.S162= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV57250830; called by muse, mutect2, varscan2
- FGD5 | c.3780G>A p.R1260= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV53242696; called by muse, mutect2, varscan2
- IPO9 | c.1272A>C p.A424= | Silent (SNP) | VAF 63/218 reads (29%) | catalogued as COSV64233710; called by muse, mutect2, varscan2
- MEGF8 | c.612G>A p.L204= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV52084713; called by muse, mutect2, varscan2
- MGA | c.7596G>A p.K2532= (on ENST00000219905 / NM_001164273.1; = p.K2323= on NM_001080541.2) | Silent (SNP) | VAF 85/153 reads (56%) | catalogued as COSV54953328, COSV54953834; called by muse, mutect2, varscan2
- NUP54 | c.264A>G p.G88= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV53575562; called by muse, mutect2
- PGBD5 | c.882C>T p.C294= (on ENST00000525115; = p.C363= on NM_001258311.2) | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as rs1353673493, COSV58410960; called by muse, mutect2, varscan2
- PLAU | c.567C>T p.N189= | Silent (SNP) | VAF 80/151 reads (53%) | catalogued as COSV65641345; called by muse, mutect2, varscan2
- SLC26A3 | c.1164C>T p.F388= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV60640293; called by muse, mutect2, varscan2
- STEAP1B | c.489C>T p.Y163= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as rs571881121, COSV101303713, COSV68345818; called by muse, mutect2, varscan2
- TMEM247 | c.276G>T p.L92= | Silent (SNP) | VAF 69/128 reads (54%) | catalogued as COSV71363706; called by muse, mutect2, varscan2
- TMPRSS11D | c.987C>T p.V329= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV52223403; called by muse, mutect2, varscan2
- HSP90AB1 | c.*179T>C | 3'UTR (SNP) | VAF 19/172 reads (11%) | catalogued as rs1357106752, COSV99240788; called by muse, mutect2, varscan2
- NPY2R | c.*321A>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100279358; called by muse, mutect2
